Somatic mutation profile of tumor specimen MP2PRT-PASXEP-TMP1-A (aliquot MP2PRT-PASXEP-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASXEP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.8 years (1,031 days).
Specimen MP2PRT-PASXEP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95b19e5b-fb46-40c2-8064-3d1bf98b4bd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASXEP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASXEP-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7eaf1c22-50c8-42a2-86fa-a3b766090349

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 104/294 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 172/416 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376760625; called by muse, mutect2
- SLIT2 | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 151/329 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747165909; called by muse, varscan2
- VCAN | c.9562C>T p.R3188C | Missense Mutation (SNP) | VAF 157/368 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768294015, COSV54108143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPH | c.2010G>C p.M670I (on ENST00000343002; = p.M403I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/796 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CROT | c.1011C>T p.N337= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs1184894383; called by muse, mutect2, varscan2
- DLC1 | c.1572C>T p.D524= (on ENST00000276297 / NM_001348081.2; = p.D87= on NM_006094.5) | Silent (SNP) | VAF 24/287 reads (8%) | catalogued as rs566023348; called by muse, mutect2
- FCSK | c.2229C>T p.D743= | Silent (SNP) | VAF 226/439 reads (51%) | catalogued as rs768446096; called by muse, mutect2, varscan2
- GRK6 | c.1713G>A p.E571= (on ENST00000355472 / NM_001004106.3; = p.S572N on NM_002082.3) | Silent (SNP) | VAF 205/472 reads (43%) | catalogued as rs767052288; called by muse, mutect2, varscan2
- IRGC | c.291G>A p.S97= | Silent (SNP) | VAF 223/552 reads (40%) | catalogued as rs11555892; called by muse, mutect2, varscan2
- PDZK1 | c.255A>G p.L85= | Silent (SNP) | VAF 18/40 reads (45%) | called by mutect2, varscan2
- SSC5D | c.1482T>C p.D494= | Silent (SNP) | VAF 222/520 reads (43%) | catalogued as rs899397368; called by muse, mutect2, varscan2
